Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAER, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAER-01A (Primary Tumor).

Department of Pathology

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
W 3/13/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 10 cm; superficial invasion of rete testis; no angio-invasion; no invasion of tunica albuginea; epididymis free of tumor; surgical margin spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 07c5ccec-0525-4351-b6ab-8f4b390fcb51 (TCGA-2G-AAER-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).